Somatic mutation profile of tumor specimen MMRF_1617_1_BM_CD138pos (aliquot MMRF_1617_1_BM_CD138pos_T1_KHS5U_K14084) from MMRF case MMRF_1617, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.6 years (17,400 days).
Specimen MMRF_1617_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd9a8341-a4a7-4076-bae8-107032533af9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1617_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1617_1_PB_Whole_C1_KHS5U_K14074; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71f3ebf7-3cc7-497b-be82-0982d7d6ac14

The open-access MAF lists 51 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 14, Missense Mutation 14, Silent 8, Intron 3, 5'Flank 3, RNA 2, 5'UTR 2, 3'Flank 2, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.1271A>T p.D424V (on ENST00000373993 / NM_138932.2; = p.D416V on NM_014576.4) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51023755; called by muse, mutect2, varscan2
- ARHGAP27 | c.1063C>T p.R355W (on ENST00000428638 / NM_001282290.1; = p.R14W on NM_199282.3) | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772027234; called by muse, mutect2, varscan2
- MKS1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV56596864; called by muse, varscan2
- PXDN | c.2928C>G p.H976Q | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as COSV53234009; called by muse, mutect2, varscan2
- RIMS2 | c.974G>A p.R325K (on ENST00000666250 / NM_001348490.2; = p.R133K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/239 reads (45%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.621); catalogued as COSV51712637; called by muse, mutect2, varscan2
- TMEM131L | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs142713810; called by muse, mutect2, varscan2
- TRAPPC10 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs149191855, COSV99379031; called by muse, mutect2, varscan2
- TSGA10IP | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs375846484, COSV73245211; called by muse, mutect2, varscan2
- USH2A | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV56352056; called by muse, mutect2, varscan2
- CIZ1 | c.2487+2_2487+6delinsG p.X829_splice | Splice Site (DEL) | VAF 70/159 reads (44%) | called by pindel, varscan2*
- FAAH | c.1239G>A p.W413* | Nonsense Mutation (SNP) | VAF 128/232 reads (55%) | called by muse, mutect2, varscan2
- LDB1 | c.542G>A p.R181Q (on ENST00000425280 / NM_001321612.2; = p.R145Q on NM_003893.5) | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- MCTP2 | c.1400_1401del p.L467Hfs*10 | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- OMP | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 125/265 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PHYHIPL | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2
- SEMA4C | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 129/235 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF445 | c.2716A>G p.I906V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ABCA13 | c.1482G>A p.E494= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- ABCD1 | c.984T>A p.V328= | Silent (SNP) | VAF 113/230 reads (49%) | called by muse, mutect2, varscan2
- ETS1 | c.690C>T p.V230= | Silent (SNP) | VAF 91/203 reads (45%) | catalogued as rs747494573, COSV60093526; called by muse, mutect2, varscan2
- IRX2 | c.303C>T p.H101= | Silent (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- OXER1 | c.195C>T p.P65= | Silent (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- PLIN1 | c.1428G>A p.T476= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs1222799124; called by muse, mutect2, varscan2
- PRKD1 | c.1524C>G p.V508= | Silent (SNP) | VAF 71/180 reads (39%) | catalogued as COSV59576701; called by muse, mutect2, varscan2
- REST | c.663C>T p.C221= | Silent (SNP) | VAF 64/139 reads (46%) | catalogued as rs1219807503; called by muse, mutect2, varscan2
- AL645933.1 | chr6:31464059 C>A | 5'Flank (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- ATP1B1 | c.*230T>G | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020995 C>G | 5'Flank (SNP) | VAF 76/163 reads (47%) | catalogued as COSV55849233, COSV55850852; called by muse, mutect2, varscan2
- CADM2 | chr3:84959009 G>A | 5'Flank (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- CYLC2 | c.*696A>C | 3'UTR (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- FAM180A | c.-68G>A | 5'UTR (SNP) | VAF 46/97 reads (47%) | catalogued as rs1446153766, COSV100647210; called by muse, mutect2, varscan2
- H2AJ | chr12:14776594 T>C | 3'Flank (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- IL1R1 | c.1304-285C>T | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- LONRF3 | c.*262A>T | 3'UTR (SNP) | VAF 10/50 reads (20%) | catalogued as rs1262435719; called by muse, varscan2
- LONRF3 | c.*277T>A | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, varscan2
- MED10 | c.*396G>A | 3'UTR (SNP) | VAF 50/109 reads (46%) | catalogued as rs185959106; called by muse, mutect2, varscan2
- MEIS1 | c.1024+203del | Intron (DEL) | VAF 40/100 reads (40%) | catalogued as rs958399132; called by mutect2, varscan2
- MMP17 | chr12:131851776 C>A | 3'Flank (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- PALLD | c.*1222G>A | 3'UTR (SNP) | VAF 60/101 reads (59%) | called by muse, mutect2, varscan2
- PCDH10 | c.*460A>C | 3'UTR (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- PCDH15 | c.*3489T>G | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2
- PFKFB3 | c.-137T>A | 5'UTR (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- SPARC | c.*47C>A | 3'UTR (SNP) | VAF 206/438 reads (47%) | called by muse, mutect2, varscan2
- STK32B | c.*1793del | 3'UTR (DEL) | VAF 36/82 reads (44%) | catalogued as rs981039587; called by mutect2, varscan2
- TACC1 | c.*975T>G | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- TAP2 | c.1462-38G>A | Intron (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- TOP3BP1 | n.1158C>T | RNA (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- UBXN10 | c.*2632C>T | 3'UTR (SNP) | VAF 55/123 reads (45%) | called by muse, mutect2, varscan2
- UGT2B27P | n.593T>C | RNA (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2, varscan2
- WNT1 | c.*135T>C | 3'UTR (SNP) | VAF 57/110 reads (52%) | called by muse, mutect2, varscan2
- ZHX3 | c.*1217G>A | 3'UTR (SNP) | VAF 77/148 reads (52%) | called by muse, mutect2, varscan2
